Somatic mutation profile of tumor specimen ALCH-B1W9-TTP1-A (aliquot ALCH-B1W9-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1W9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.6 years (25,060 days).
Specimen ALCH-B1W9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7345fb50-38b7-41e8-8fea-375d26b5bddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1W9-NB1-A (Blood Derived Normal), aliquot ALCH-B1W9-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6c623dc-ea60-4ea9-8c5b-3b42b18a9197

The open-access MAF lists 523 somatic variants for this specimen: 348 protein-altering or splice-affecting, 112 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 307, Silent 112, Intron 24, Nonsense Mutation 24, RNA 13, 3'UTR 9, 3'Flank 6, 5'Flank 6, Splice Site 6, 5'UTR 5, Splice Region 5, Frame Shift Del 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLUD1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 53/461 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.582); catalogued as rs797045597, CM001182; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYLK | c.4415+1G>A p.X1472_splice | Splice Site (SNP) | VAF 32/400 reads (8%) | catalogued as rs1430822242, COSV60603856; ClinVar: likely pathogenic; called by muse, mutect2
- NF1 | c.3827G>C p.R1276P | Missense Mutation (SNP) | VAF 120/344 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854556, CM000802, CM983421, COSV100648616, COSV62196628, COSV62224419; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RUNX1 | c.270+1G>C p.X90_splice (on ENST00000344691 / NM_001001890.3; = p.X117_splice on NM_001754.5) | Splice Site (SNP) | VAF 30/407 reads (7%) | catalogued as rs1060502579, CS086072, CS1312705, COSV55897469; ClinVar: likely pathogenic; called by muse, mutect2
- SNRPD3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 30/97 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53183301, COSV53184122; called by muse, mutect2, varscan2
- A2M | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV59387039; called by muse, mutect2, varscan2
- ADGB | c.1256C>A p.A419E | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV58864482; called by muse, mutect2, varscan2
- AKAP6 | c.3147+1G>A p.X1049_splice | Splice Site (SNP) | VAF 14/484 reads (3%) | catalogued as COSV55204624; called by muse, mutect2
- ANKRD1 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.01); catalogued as rs145387010, CM094353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APLP1 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1306154986; called by muse, mutect2
- APOB | c.12199C>A p.L4067I | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs1311058149; called by muse, mutect2
- APP | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61006980; called by muse, mutect2
- ASPG | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs773708256; called by muse, mutect2, varscan2
- CARS2 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1326665781; called by muse, mutect2, varscan2
- CD163L1 | c.1492G>T p.G498W | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549968; called by muse, mutect2, varscan2
- CDHR2 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 70/163 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56140055; called by muse, mutect2, varscan2
- CLK4 | c.1440G>T p.K480N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); catalogued as rs200310750; called by muse, mutect2
- COLQ | c.636A>G p.K212= | Splice Region (SNP) | VAF 39/495 reads (8%) | catalogued as CD158783; called by muse, mutect2
- CSMD1 | c.6884G>T p.G2295V (on ENST00000520002; = p.G2294V on NM_033225.6) | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153018; called by muse, mutect2, varscan2
- CSN1S1 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 26/202 reads (13%) | catalogued as rs1553884363; called by muse, varscan2
- CYP4F2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145875499; called by muse, mutect2, varscan2
- DACT1 | c.2050G>T p.E684* | Nonsense Mutation (SNP) | VAF 35/116 reads (30%) | catalogued as COSV60020811; called by muse, mutect2, varscan2
- DACT2 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.517); catalogued as rs771407706; called by muse, mutect2, varscan2
- DACT2 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs904090536; called by muse, mutect2, varscan2
- DTL | c.230G>T p.R77L | Missense Mutation (SNP) | VAF 46/208 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV65341994, COSV65343129; called by muse, mutect2, varscan2
- E4F1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs765209050; called by muse, mutect2, varscan2
- EDRF1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | catalogued as COSV61764982; called by muse, mutect2
- FAM135B | c.1139G>T p.R380L | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52724669; called by muse, mutect2, varscan2
- FASN | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1438367361; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLII | c.1429del p.D477Tfs*25 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV58946380; called by mutect2, pindel*
- FN1 | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 35/498 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs763981789; called by muse, mutect2
- FRAS1 | c.7454C>T p.T2485M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs771971412, COSV53589559, COSV53629669; called by muse, mutect2, varscan2
- FSIP2 | c.5653T>A p.Y1885N | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV58094134; called by muse, mutect2, varscan2
- FTMT | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs796443362, COSV58421147; called by muse, mutect2, varscan2
- GADL1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.088); catalogued as COSV99031348; called by muse, mutect2
- GAS1 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.279); catalogued as CM103791; called by muse, mutect2, varscan2
- GBA | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV59170888; called by muse, mutect2
- GRIA1 | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99598431; called by muse, mutect2
- IQGAP1 | c.3071G>T p.R1024L | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV51583983; called by muse, mutect2
- KCNH5 | c.1598G>C p.R533T | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV100528438; called by muse, mutect2
- LAMA2 | c.5596A>T p.M1866L | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV70358153; called by muse, mutect2, varscan2
- LAMA2 | c.5845G>T p.A1949S | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs746608333; called by muse, mutect2, varscan2
- LRP6 | c.2840T>C p.M947T | Missense Mutation (SNP) | VAF 34/385 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99744748; called by muse, mutect2
- LRRIQ3 | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100598783; called by muse, mutect2, varscan2
- LYST | c.6148C>T p.R2050W | Missense Mutation (SNP) | VAF 59/317 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs773494262, COSV67703838; called by muse, mutect2, varscan2
- MAP3K5 | c.3815G>T p.R1272L | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV62887495; called by muse, mutect2, varscan2
- MASP1 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as rs761251394; called by muse, mutect2
- MDN1 | c.10073G>T p.G3358V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV65524208; called by muse, mutect2
- MRGPRG | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV60040020; called by muse, mutect2, varscan2
- MROH9 | c.153C>G p.S51R | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs746302834; called by mutect2, varscan2
- MTA2 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 36/336 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV99545410; called by muse, mutect2, varscan2
- MUC12 | c.9157C>T p.P3053S (on ENST00000379442; = p.P2910S on NM_001164462.1) | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.955); catalogued as rs113645398, COSV65208736; called by muse, mutect2
- MUC16 | c.18514C>A p.L6172M | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.557); catalogued as COSV67503785; called by muse, mutect2, varscan2
- MYH7 | c.115G>C p.V39L | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as CM031265, COSV100805538; called by muse, mutect2, varscan2
- MYT1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 35/147 reads (24%) | catalogued as COSV60511425; called by muse, mutect2, varscan2
- NEK10 | c.3131A>G p.Y1044C | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1180214647, COSV55359809; called by muse, varscan2
- NF1 | c.7102G>T p.E2368* (on ENST00000358273 / NM_001042492.3; = p.E2347* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 45/374 reads (12%) | catalogued as COSV62204812; called by muse, mutect2, varscan2
- NPHS1 | c.3481+1G>T p.X1161_splice | Splice Site (SNP) | VAF 47/340 reads (14%) | catalogued as rs142883811, CS011564; called by muse, mutect2, varscan2
- NUP210 | c.4085A>G p.N1362S | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1302811838, COSV54410674; called by muse, mutect2
- OR52E2 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58612883; called by muse, mutect2
- OR5B2 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.03); catalogued as rs753412750, COSV56907674; called by muse, mutect2, varscan2
- OR8U1 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 12/119 reads (10%) | catalogued as COSV56415131, COSV56415358; called by muse, mutect2
- OVCH1 | c.1940C>A p.A647D | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV58959015; called by muse, mutect2, varscan2
- PABPC5 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57040355, COSV99058203; called by muse, mutect2, varscan2
- PAPOLB | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.153); catalogued as rs1232353624; called by muse, mutect2
- PCDHB5 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as rs1554275831, COSV50649076; called by muse, mutect2, varscan2
- PDK1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs991034797; called by mutect2, varscan2
- PHACTR3 | c.1072G>T p.E358* | Nonsense Mutation (SNP) | VAF 50/346 reads (14%) | catalogued as COSV63026003; called by muse, mutect2, varscan2
- PKHD1 | c.11567A>C p.K3856T | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1160507513, COSV64396360, COSV64404691; called by muse, mutect2, varscan2
- PKHD1 | c.2042C>T p.S681F | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV61874507; called by muse, mutect2
- PLG | c.1256C>A p.A419D | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.616); catalogued as COSV51983159; called by muse, mutect2
- POLA2 | c.1165G>C p.V389L | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as COSV55480473; called by muse, mutect2
- POTEM | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV69152208, COSV69155162; called by muse, varscan2
- PPEF1 | c.633G>C p.E211D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62996864; called by muse, mutect2, varscan2
- PTPRN2 | c.1141G>C p.V381L | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV67026747; called by muse, mutect2
- PXDNL | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62491012; called by muse, mutect2, varscan2
- PYDC2 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.826); catalogued as COSV72921310; called by muse, mutect2
- PZP | c.2127G>T p.E709D | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV54362431; called by muse, mutect2, varscan2
- RELN | c.1858C>A p.H620N | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as rs1483467031; called by muse, mutect2
- RHOU | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 14/518 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64209206; called by muse, mutect2
- RNF17 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs750750208, COSV55044120; called by muse, mutect2, varscan2
- RP1L1 | c.3857G>A p.S1286N | Missense Mutation (SNP) | VAF 58/541 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs761545193; called by muse, varscan2
- RTTN | c.3049G>T p.V1017L | Missense Mutation (SNP) | VAF 48/416 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as rs780594967; called by muse, mutect2, varscan2
- RYR2 | c.11085G>A p.M3695I | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs1181977194, COSV100767171; called by muse, mutect2
- SCAF4 | c.3406del p.E1136Kfs*18 | Frame Shift Del (DEL) | VAF 23/153 reads (15%) | catalogued as COSV54256594; called by mutect2, pindel, varscan2
- SCN1A | c.3407C>A p.S1136* (on ENST00000303395 / NM_001202435.3; = p.S1125* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/236 reads (10%) | catalogued as COSV57668986; called by muse, mutect2, varscan2
- SEBOX | c.361C>A p.R121S | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs782063205; called by muse, mutect2
- SIPA1L2 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99476813; called by muse, mutect2, varscan2
- SLC16A7 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV53900291; called by muse, mutect2, varscan2
- SLC27A6 | c.1243C>A p.H415N | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV52486681; called by muse, mutect2, varscan2
- SLC39A1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV57842547; called by muse, varscan2
- SP110 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 13/445 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1317519602; ClinVar: uncertain significance; called by muse, mutect2
- SSX7 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1342577940; called by muse, mutect2, varscan2
- STAB2 | c.464T>G p.L155* | Nonsense Mutation (SNP) | VAF 22/316 reads (7%) | catalogued as COSV66335883; called by muse, mutect2
- STPG2 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54789035; called by muse, mutect2
- STYXL2 | c.2678T>C p.I893T | Missense Mutation (SNP) | VAF 26/461 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as rs746805685; called by muse, mutect2
- TLE1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 7/156 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1305709224; called by muse, mutect2
- TLR4 | c.628C>A p.L210M (on ENST00000355622 / NM_138554.5; = p.L170M on NM_003266.4) | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV62922683; called by muse, mutect2, varscan2
- TMIE | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs781582246; called by muse, mutect2
- TRPC7 | c.1040C>A p.S347Y | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV61458280; called by muse, mutect2, varscan2
- TRRAP | c.4850C>T p.P1617L (on ENST00000359863 / NM_001244580.1; = p.P1599L on NM_003496.3) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.982); catalogued as rs1387671388; called by muse, mutect2, varscan2
- TRUB1 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53930846; called by muse, mutect2
- TSHZ3 | c.1840G>T p.V614L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53666219; called by muse, mutect2
- UMOD | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs1182373301; called by muse, mutect2, varscan2
- UNC13A | c.545G>T p.W182L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.901); catalogued as rs1412991495; called by muse, mutect2, varscan2
- WBP11 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 26/332 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.565); catalogued as rs761641176, COSV53764006; called by muse, mutect2
- XKR4 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1298435757; called by muse, mutect2
- ZBTB4 | c.2188G>C p.D730H | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.65); catalogued as COSV60979207; called by muse, mutect2
- ZKSCAN8 | c.980G>A p.C327Y | Missense Mutation (SNP) | VAF 48/577 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751267874; called by muse, mutect2
- ZNF568 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 33/215 reads (15%) | catalogued as COSV99067992; called by muse, mutect2, varscan2
- A2M | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 24/545 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2
- ACMSD | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.318); called by muse, mutect2
- ACOXL | c.1608G>T p.M536I (on ENST00000389811 / NM_001371254.1; = p.M506I on NM_001142807.4) | Missense Mutation (SNP) | VAF 12/257 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ACP7 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ACSM5 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADAMTS1 | c.951G>T p.K317N | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.666); called by muse, mutect2
- ADAMTS20 | c.2851G>T p.D951Y | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); called by muse, mutect2
- ADGRL3 | c.2363G>T p.G788V (on ENST00000506720 / NM_001322402.2; = p.G720V on NM_015236.6) | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AGO4 | c.1423A>T p.M475L | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, varscan2
- AHNAK2 | c.12583G>A p.G4195S | Missense Mutation (SNP) | VAF 95/351 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- AKAP12 | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1C3 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 22/471 reads (5%) | called by muse, mutect2
- ANK3 | c.7985C>G p.A2662G | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.048); called by muse, mutect2
- ANK3 | c.7186G>T p.E2396* | Nonsense Mutation (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- ANKRD30B | c.3625G>C p.A1209P | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AP3D1 | c.2567G>C p.R856T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.192); called by muse, mutect2
- APP | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AQP12A | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARPP21 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2
- ASH1L | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 254/976 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASPN | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 104/487 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- ASXL3 | c.3322G>T p.A1108S | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ATF1 | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 82/280 reads (29%) | called by muse, mutect2, varscan2
- ATP10D | c.1793T>A p.V598E | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BNC2 | c.933C>G p.H311Q | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2
- BOD1L1 | c.7199T>A p.L2400* | Nonsense Mutation (SNP) | VAF 23/163 reads (14%) | called by muse, mutect2, varscan2
- BRINP1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BSN | c.7948T>A p.S2650T | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- C12orf71 | c.195G>T p.R65S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C15orf62 | c.127_129dup p.H43dup | In Frame Ins (INS) | VAF 20/181 reads (11%) | called by mutect2, pindel
- CALML3 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CARMIL3 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CASK | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CCDC74B | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.199); called by muse, mutect2
- CD19 | c.472G>C p.V158L | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- CD1E | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- CHD5 | c.4267G>T p.G1423C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD6 | c.3371A>G p.H1124R | Missense Mutation (SNP) | VAF 107/485 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRM2 | c.280G>C p.V94L | Missense Mutation (SNP) | VAF 44/702 reads (6%) | SIFT tolerated (0.96); PolyPhen benign (0.015); called by muse, mutect2
- CLCN1 | c.2715G>T p.E905D | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNTNAP4 | c.2366-2A>T p.X789_splice | Splice Site (SNP) | VAF 40/230 reads (17%) | called by muse, varscan2
- COL14A1 | c.4901G>T p.R1634M | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- COL19A1 | c.3116C>A p.S1039Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL5A2 | c.4200C>G p.N1400K | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2
- COPG1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- COPZ2 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 118/281 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CPQ | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CPXM2 | c.2019C>A p.A673= | Splice Region (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2
- CSMD3 | c.8033G>T p.G2678V (on ENST00000297405 / NM_001363185.1; = p.G2574V on NM_052900.3) | Missense Mutation (SNP) | VAF 136/451 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD3 | c.4120G>T p.G1374C (on ENST00000297405 / NM_001363185.1; = p.G1270C on NM_052900.3) | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSMD3 | c.2792A>T p.H931L (on ENST00000297405 / NM_001363185.1; = p.H827L on NM_052900.3) | Missense Mutation (SNP) | VAF 27/468 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2
- CSPP1 | c.3358G>A p.E1120K (on ENST00000676605; = p.E1079K on NM_024790.6) | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- CUL2 | c.1050T>A p.F350L | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- CYP2A7 | c.788C>A p.S263Y | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); called by muse, mutect2
- CYYR1 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DMD | c.2946G>T p.L982F | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- DNAH14 | c.10341G>C p.Q3447H (on ENST00000445597; = p.Q4455H on NM_001367479.1) | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, varscan2
- DNAH7 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.12569A>G p.Q4190R | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPH7 | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- DTHD1 | c.1093T>A p.S365T (on ENST00000456874; = p.S200T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.255); called by muse, mutect2
- ECE2 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EFHC2 | c.1416G>T p.R472S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- ESCO1 | c.1432A>T p.R478W | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FAM229B | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- FAM47A | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FAM83G | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- FBH1 | c.2828G>T p.G943V (on ENST00000362091 / NM_178150.3; = p.G994V on NM_032807.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FBN2 | c.2567G>T p.C856F | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- FER1L6 | c.5122C>A p.L1708M | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FHOD1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, varscan2
- FLNB | c.4102C>G p.P1368A | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMN1 | c.1340T>G p.V447G | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- FOXD4L3 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); called by mutect2, varscan2
- FRG2C | c.698C>G p.A233G | Missense Mutation (SNP) | VAF 10/396 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); called by muse, mutect2
- GABRA4 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLRB | c.894A>C p.R298S | Missense Mutation (SNP) | VAF 36/526 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- GP1BB | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- GPATCH1 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- GPR137B | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- GPR139 | c.938T>A p.F313Y | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- GPR141 | c.413G>T p.G138V | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR31 | c.710C>A p.P237H | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPX3 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- GRIA4 | c.751A>T p.R251W | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRM3 | c.1874C>G p.S625* | Nonsense Mutation (SNP) | VAF 50/135 reads (37%) | called by muse, mutect2, varscan2
- GTPBP4 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- H3-2 | c.245A>T p.D82V | Missense Mutation (SNP) | VAF 30/516 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- H4C6 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2
- HCN4 | c.1157T>A p.L386* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- HDC | c.233A>T p.H78L | Missense Mutation (SNP) | VAF 26/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC1 | c.10572G>T p.Q3524H | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HIP1 | c.2767G>T p.V923L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HPF1 | c.320G>T p.R107M | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IARS2 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV1-36 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); called by muse, mutect2
- IL7R | c.856C>A p.L286I | Missense Mutation (SNP) | VAF 101/772 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INF2 | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- INHBC | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- INPP5F | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 9/203 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- INTS6 | c.1339G>C p.G447R | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- IRF2BP1 | c.483G>T p.L161F | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ITGA8 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- JAKMIP1 | c.1690C>A p.Q564K | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- JAKMIP1 | c.344C>G p.A115G | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA2026 | c.527A>T p.H176L | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KIF14 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 65/243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIFAP3 | c.572T>G p.V191G | Missense Mutation (SNP) | VAF 68/406 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- KLF15 | c.1109G>T p.R370L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL20 | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.499); called by muse, mutect2
- KREMEN2 | c.1100-5C>A | Splice Region (SNP) | VAF 11/111 reads (10%) | called by muse, mutect2
- KRT75 | c.234C>A p.S78R | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- KRTAP6-1 | c.170G>T p.C57F | Missense Mutation (SNP) | VAF 48/302 reads (16%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMA5 | c.8176G>T p.A2726S | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LBR | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- LILRA6 | c.1438G>T p.G480W | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- LPCAT1 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRFN2 | c.527A>T p.H176L | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- LYST | c.6149G>T p.R2050L | Missense Mutation (SNP) | VAF 62/323 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAD1L1 | c.1901A>T p.Y634F | Missense Mutation (SNP) | VAF 84/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MAP3K4 | c.1339A>C p.T447P | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MARCHF1 | c.646T>A p.Y216N (on ENST00000274056; = p.Y199N on NM_017923.4) | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MATR3 | c.1182G>T p.V394= | Splice Region (SNP) | VAF 37/496 reads (7%) | called by muse, mutect2
- MCM10 | c.1211T>A p.V404E (on ENST00000484800 / NM_182751.3; = p.V403E on NM_018518.5) | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MEP1A | c.743T>G p.I248S | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.077); called by muse, mutect2
- MIPOL1 | c.290G>A p.C97Y | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MLXIP | c.1871A>C p.E624A | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.696); called by muse, mutect2
- MPO | c.1256T>A p.L419* | Nonsense Mutation (SNP) | VAF 23/346 reads (7%) | called by muse, mutect2
- MRC1 | c.2114C>A p.A705D | Missense Mutation (SNP) | VAF 160/644 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- MUC16 | c.35600T>C p.L11867P | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYBPC1 | c.72A>T p.K24N | Missense Mutation (SNP) | VAF 42/484 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- MYH1 | c.1057T>C p.Y353H | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NCAM2 | c.2123del p.G708Efs*7 | Frame Shift Del (DEL) | VAF 77/321 reads (24%) | called by mutect2, pindel, varscan2
- NEMF | c.2408C>G p.S803C | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.125); called by muse, mutect2
- NEXMIF | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NFRKB | c.13G>T p.D5Y (on ENST00000446488 / NM_001143835.2; = p.D18Y on NM_006165.3) | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- NPAP1 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- NPC1L1 | c.1277T>G p.L426R | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); called by muse, mutect2
- NPC2 | c.306A>C p.Q102H | Missense Mutation (SNP) | VAF 32/724 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- NPY1R | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- NPY2R | c.1109G>C p.G370A | Missense Mutation (SNP) | VAF 112/636 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRG3 | c.1814G>A p.G605D (on ENST00000404547 / NM_001370084.1; = p.G581D on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/474 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NRP1 | c.1384A>G p.I462V | Missense Mutation (SNP) | VAF 25/295 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- NTRK3 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 133/560 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OBSCN | c.2255A>T p.Y752F | Missense Mutation (SNP) | VAF 47/160 reads (29%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- OR14A16 | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2V1 | c.737T>A p.L246Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR4S2 | c.425T>A p.M142K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); called by muse, mutect2
- OR51F1 | c.158T>A p.V53E | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR8H3 | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.483); called by muse, mutect2
- OTOGL | c.1228G>T p.E410* (on ENST00000547103; = p.E401* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 64/250 reads (26%) | called by muse, mutect2, varscan2
- OVCH1 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, varscan2
- PCDH10 | c.3120C>A p.C1040* | Nonsense Mutation (SNP) | VAF 26/250 reads (10%) | called by muse, varscan2
- PCDH11Y | c.1795A>T p.S599C (on ENST00000400457 / NM_032973.2; = p.S588C on NM_032971.3) | Missense Mutation (SNP) | VAF 86/233 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PCDH17 | c.2517A>T p.Q839H | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PCDH17 | c.3088C>A p.Q1030K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- PCDH19 | c.3004G>T p.V1002F (on ENST00000373034 / NM_001184880.2; = p.V954F on NM_020766.3) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCDHB1 | c.2044A>G p.R682G | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDHB12 | c.1031C>G p.A344G | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); called by muse, mutect2
- PCDHB7 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGB7 | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCYOX1 | c.1445A>T p.Y482F | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PF4V1 | c.38C>A p.T13N | Missense Mutation (SNP) | VAF 70/304 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLDB2 | c.1851G>C p.E617D | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PIK3R1 | c.1769G>C p.R590P (on ENST00000521381 / NM_181523.3; = p.R320P on NM_181504.4) | Missense Mutation (SNP) | VAF 39/539 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.267); called by muse, mutect2
- PIP4K2B | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- PKD1L1 | c.1297T>C p.Y433H | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PKP2 | c.83C>A p.S28Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLAT | c.850C>A p.R284S | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLCB1 | c.2797C>A p.L933M | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PLEC | c.8141A>T p.E2714V (on ENST00000322810 / NM_201380.4; = p.E2604V on NM_000445.5) | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- PLXNB1 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PPP1R3A | c.2904T>A p.Y968* | Nonsense Mutation (SNP) | VAF 44/451 reads (10%) | called by muse, mutect2, varscan2
- PRDM8 | c.913A>T p.I305F | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PTH2 | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.037); called by muse, varscan2
- PTPRN | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PZP | c.2507C>A p.A836D | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAG1 | c.2360T>C p.F787S | Missense Mutation (SNP) | VAF 28/295 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- RALGAPA2 | c.2114T>A p.V705E | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RBM20 | c.2740G>T p.V914F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHO | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMBP2 | c.1452A>T p.A484= | Splice Region (SNP) | VAF 7/17 reads (41%) | called by muse, varscan2
- ROCK1 | c.3234G>A p.M1078I | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RPTN | c.1004A>T p.D335V | Missense Mutation (SNP) | VAF 53/826 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- SCFD1 | c.1394A>T p.Q465L | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- SCFD2 | c.1466A>T p.K489I | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- SEPTIN1 | c.707A>G p.D236G (on ENST00000321367; = p.D189G on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.399); called by muse, mutect2
- SEPTIN14 | c.837T>A p.C279* | Nonsense Mutation (SNP) | VAF 34/96 reads (35%) | called by muse, varscan2
- SH3PXD2A | c.937G>T p.G313C (on ENST00000369774 / NM_001365079.1; = p.G285C on NM_014631.2) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC14 | c.611_612insT p.E205Rfs*73 | Frame Shift Ins (INS) | VAF 19/67 reads (28%) | called by mutect2, pindel*, varscan2
- SLC19A2 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 20/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC35B3 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLC4A1 | c.1574C>A p.S525Y | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC4A3 | c.2380G>T p.V794L | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- SLC5A12 | c.1727G>A p.S576N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- SOAT2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTA1 | c.4303A>T p.K1435* | Nonsense Mutation (SNP) | VAF 26/821 reads (3%) | called by muse, mutect2
- STAM | c.368C>G p.P123R | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- STXBP5L | c.2737T>C p.Y913H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.09); called by muse, varscan2
- SUCO | c.1330A>T p.S444C | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TACR2 | c.158T>A p.I53N | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- TAFA1 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TBC1D20 | c.295G>C p.V99L | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBC1D7 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBR1 | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TDRD15 | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECPR1 | c.2959del p.Q987Sfs*50 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, varscan2
- TFAP2B | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- THBS2 | c.3350G>T p.R1117M | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TMEM155 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TMEM178B | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMEM239 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TMIGD2 | c.526C>A p.R176S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TMTC1 | c.868T>C p.S290P (on ENST00000539277 / NM_001193451.2; = p.S182P on NM_175861.3) | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- TMTC1 | c.623G>T p.S208I (on ENST00000539277 / NM_001193451.2; = p.S100I on NM_175861.3) | Missense Mutation (SNP) | VAF 22/427 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- TOPAZ1 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.368); called by muse, mutect2
- TRA2A | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 30/644 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- TRAF3IP2 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- TRAV9-1 | c.213G>T p.K71N | Missense Mutation (SNP) | VAF 68/494 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.044); called by mutect2, varscan2
- TRIM51 | c.885A>C p.R295S | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.045); called by muse, mutect2
- TRIM58 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.156); called by muse, mutect2
- TRPC5 | c.1078A>G p.I360V | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TRPV4 | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TTK | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- TXLNA | c.869A>C p.Q290P | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.302); called by muse, mutect2
- UBASH3A | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2
- UBQLN3 | c.1587G>T p.Q529H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- UGT2B10 | c.1514T>G p.F505C | Missense Mutation (SNP) | VAF 35/387 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2
- USH2A | c.11011C>A p.P3671T | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2
- USPL1 | c.3109G>T p.V1037F | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- VPS54 | c.2560A>T p.I854L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- WWC1 | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 35/470 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- YWHAZ | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZBBX | c.1549C>A p.Q517K | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.5981C>A p.P1994Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFR | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 34/848 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZIC4 | c.711G>T p.E237D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ZNF254 | c.1462A>G p.K488E | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRG4 | c.5181T>A p.S1727= | Silent (SNP) | VAF 34/76 reads (45%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3039C>G p.A1013= (on ENST00000506720 / NM_001322402.2; = p.A945= on NM_015236.6) | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as rs1271460468; called by mutect2, varscan2
- AHNAK2 | c.8355C>A p.A2785= | Silent (SNP) | VAF 30/294 reads (10%) | catalogued as rs368948621; called by muse, mutect2, varscan2
- ALKBH5 | c.966C>G p.P322= | Silent (SNP) | VAF 50/159 reads (31%) | called by muse, mutect2, varscan2
- AMBN | c.12T>C p.S4= | Silent (SNP) | VAF 96/430 reads (22%) | called by muse, mutect2, varscan2
- ANKIB1 | c.1275A>T p.P425= | Silent (SNP) | VAF 28/395 reads (7%) | called by muse, mutect2
- ATP2B2 | c.1269C>A p.P423= (on ENST00000352432; = p.P389= on NM_001683.5) | Silent (SNP) | VAF 40/256 reads (16%) | catalogued as COSV59507522; called by muse, mutect2, varscan2
- ATP6V1C2 | c.954C>A p.G318= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as rs1019971944, COSV55358270; called by muse, varscan2
- AXDND1 | c.1665T>A p.I555= | Silent (SNP) | VAF 83/311 reads (27%) | called by muse, mutect2, varscan2
- B3GNT3 | c.409C>A p.R137= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV59438943; called by muse, mutect2, varscan2
- BPIFC | c.1023C>A p.I341= | Silent (SNP) | VAF 29/195 reads (15%) | called by muse, mutect2, varscan2
- BTBD9 | c.1674G>A p.E558= | Silent (SNP) | VAF 20/341 reads (6%) | called by muse, mutect2
- C10orf71 | c.4104C>A p.S1368= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- C2orf16 | c.5844G>A p.E1948= | Silent (SNP) | VAF 35/169 reads (21%) | catalogued as rs781735482; called by muse, mutect2, varscan2
- CACNA1F | c.966A>T p.T322= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- CDC14A | c.1074C>T p.G358= | Silent (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
- CDH12 | c.2277A>T p.T759= | Silent (SNP) | VAF 198/554 reads (36%) | called by muse, mutect2, varscan2
- CDH12 | c.846C>T p.S282= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as COSV66409273; called by muse, mutect2
- CDHR1 | c.378C>A p.T126= | Silent (SNP) | VAF 15/410 reads (4%) | called by muse, mutect2
- CNTNAP4 | c.1524A>T p.P508= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- COL4A1 | c.2727C>A p.G909= | Silent (SNP) | VAF 50/305 reads (16%) | catalogued as COSV65426078; called by muse, mutect2, varscan2
- CPZ | c.1419G>A p.L473= (on ENST00000360986 / NM_001014447.3; = p.L462= on NM_003652.3) | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs371888837; called by muse, mutect2, varscan2
- CSMD1 | c.6747C>A p.L2249= (on ENST00000520002; = p.L2248= on NM_033225.6) | Silent (SNP) | VAF 14/102 reads (14%) | called by muse, mutect2
- DDX28 | c.1431G>T p.T477= | Silent (SNP) | VAF 40/236 reads (17%) | catalogued as COSV100192904; called by muse, mutect2, varscan2
- DENND4B | c.786G>C p.V262= | Silent (SNP) | VAF 147/559 reads (26%) | catalogued as COSV63411327; called by muse, mutect2, varscan2
- DNAH12 | c.1062G>T p.V354= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- DOCK2 | c.2748G>T p.L916= | Silent (SNP) | VAF 22/528 reads (4%) | called by muse, mutect2
- EBF2 | c.675G>T p.L225= | Silent (SNP) | VAF 30/198 reads (15%) | catalogued as rs1012730387, COSV68780540; called by muse, mutect2, varscan2
- EMILIN1 | c.12C>A p.R4= | Silent (SNP) | VAF 10/123 reads (8%) | called by muse, mutect2
- ENOX1 | c.1908C>G p.A636= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- EP400 | c.942G>A p.T314= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1230299970; called by mutect2, varscan2
- FAM8A1 | c.453C>T p.F151= | Silent (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- FBXO32 | c.825C>T p.S275= | Silent (SNP) | VAF 18/314 reads (6%) | catalogued as rs762433023, COSV54891218; called by muse, mutect2
- FER1L5 | c.2763C>A p.P921= (on ENST00000623019; = p.P928= on NM_001293083.2) | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- FER1L6 | c.3087C>T p.C1029= | Silent (SNP) | VAF 12/174 reads (7%) | catalogued as rs199742153, COSV67551734; called by muse, mutect2
- FTSJ1 | c.33C>T p.V11= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs1556966943; called by muse, mutect2, varscan2
- GALR3 | c.510G>A p.E170= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1256181382; called by muse, mutect2
- GP1BA | c.660G>A p.G220= | Silent (SNP) | VAF 39/263 reads (15%) | called by muse, mutect2, varscan2
- GPNMB | c.1710A>G p.G570= (on ENST00000381990 / NM_001005340.2; = p.G558= on NM_002510.3) | Silent (SNP) | VAF 22/304 reads (7%) | called by muse, mutect2
- GPR179 | c.2538C>T p.S846= (on ENST00000621958; = p.S845= on NM_001004334.4) | Silent (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2, varscan2
- GPR31 | c.711C>A p.P237= | Silent (SNP) | VAF 27/257 reads (11%) | called by muse, mutect2
- GRB10 | c.42G>T p.P14= | Silent (SNP) | VAF 203/653 reads (31%) | catalogued as rs764199937, COSV100240085; called by muse, mutect2, varscan2
- GSDMD | c.1164G>A p.L388= | Silent (SNP) | VAF 38/265 reads (14%) | called by muse, mutect2, varscan2
- GUCA2B | c.27C>G p.L9= | Silent (SNP) | VAF 42/111 reads (38%) | called by muse, mutect2, varscan2
- HDAC9 | c.2391A>T p.S797= | Silent (SNP) | VAF 23/303 reads (8%) | called by muse, mutect2
- HPS4 | c.1605C>T p.C535= | Silent (SNP) | VAF 53/206 reads (26%) | catalogued as rs1230780812; called by muse, mutect2, varscan2
- HS3ST4 | c.213C>A p.A71= | Silent (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- IGKV1D-17 | c.96C>A p.A32= | Silent (SNP) | VAF 33/730 reads (5%) | called by muse, mutect2
- IRS4 | c.3231A>G p.E1077= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs756547195; called by muse, mutect2, varscan2
- ITK | c.957C>A p.L319= | Silent (SNP) | VAF 40/471 reads (8%) | called by muse, mutect2
- ITK | c.997C>A p.R333= | Silent (SNP) | VAF 44/694 reads (6%) | catalogued as COSV70063434; called by muse, mutect2
- KCNT1 | c.1870C>A p.R624= (on ENST00000488444; = p.R643= on NM_020822.3) | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV53706081; called by muse, mutect2, varscan2
- KCNV2 | c.1455C>T p.N485= | Silent (SNP) | VAF 25/478 reads (5%) | catalogued as rs112479446; called by muse, mutect2
- KLF15 | c.1110G>T p.R370= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- KRTAP19-5 | c.141C>T p.G47= | Silent (SNP) | VAF 55/424 reads (13%) | called by muse, mutect2, varscan2
- LAMA2 | c.5595T>A p.P1865= | Silent (SNP) | VAF 49/269 reads (18%) | catalogued as rs746019110; called by muse, mutect2, varscan2
- LHX4 | c.219G>C p.G73= | Silent (SNP) | VAF 23/268 reads (9%) | called by muse, mutect2
- LILRA1 | c.1101C>A p.L367= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as COSV52178504; called by muse, mutect2, varscan2
- LONP2 | c.228G>T p.L76= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2
- LPA | c.3204C>T p.T1068= | Silent (SNP) | VAF 54/430 reads (13%) | called by muse, mutect2, varscan2
- LRRC55 | c.675T>A p.A225= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- LTBP4 | c.174C>A p.G58= (on ENST00000308370 / NM_001042544.1; = p.A15D on NM_003573.2) | Silent (SNP) | VAF 13/250 reads (5%) | called by muse, mutect2
- MTG1 | c.138G>T p.L46= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- MTMR3 | c.954C>A p.R318= | Silent (SNP) | VAF 24/193 reads (12%) | catalogued as rs1178516239; called by muse, mutect2, varscan2
- MUC16 | c.1020C>A p.A340= | Silent (SNP) | VAF 21/264 reads (8%) | catalogued as COSV101199336; called by muse, mutect2
- NOL6 | c.1023C>T p.D341= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs758414193; called by muse, mutect2, varscan2
- OR14A2 | c.873G>T p.R291= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- OR2B11 | c.372G>T p.L124= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV100275262, COSV59509341; called by muse, mutect2, varscan2
- OR2C3 | c.792C>T p.A264= | Silent (SNP) | VAF 20/295 reads (7%) | catalogued as rs781174311; called by muse, mutect2
- OR4K13 | c.777C>G p.V259= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- OR4K2 | c.435G>T p.V145= | Silent (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- OR4S2 | c.834C>A p.P278= | Silent (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
- OR51F1 | c.586T>C p.L196= | Silent (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- PAK5 | c.1495C>A p.R499= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV62022756; called by muse, mutect2, varscan2
- PAPPA2 | c.2367T>C p.T789= | Silent (SNP) | VAF 12/241 reads (5%) | called by muse, mutect2
- PIK3CG | c.897C>T p.N299= | Silent (SNP) | VAF 14/169 reads (8%) | catalogued as rs1220639059, COSV63247243, COSV63247651; called by muse, mutect2
- PLXNB1 | c.327G>T p.V109= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- POLR1B | c.1023A>G p.E341= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- PPP1R3A | c.12T>C p.S4= | Silent (SNP) | VAF 24/288 reads (8%) | catalogued as COSV52877735; called by muse, mutect2
- PRR23A | c.429C>T p.C143= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs1399508123, COSV67214708; called by muse, mutect2, varscan2
- RBBP6 | c.1683A>G p.P561= | Silent (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- RIMS2 | c.2250A>G p.G750= (on ENST00000666250 / NM_001348490.2; = p.G558= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 49/280 reads (18%) | called by muse, mutect2, varscan2
- RNF212B | c.534C>A p.S178= | Silent (SNP) | VAF 14/188 reads (7%) | called by muse, mutect2
- RTL6 | c.423G>T p.V141= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1743C>T p.D581= (on ENST00000265814 / NM_001198628.1; = p.D554= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- SALL3 | c.273C>G p.P91= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs1282662707; called by muse, mutect2, varscan2
- SHISA6 | c.1248C>G p.P416= (on ENST00000409168 / NM_001173461.1; = p.P467= on NM_207386.4) | Silent (SNP) | VAF 26/163 reads (16%) | catalogued as rs745789668; called by muse, mutect2, varscan2
- SLC26A7 | c.966C>A p.A322= | Silent (SNP) | VAF 34/527 reads (6%) | called by muse, mutect2
- SLC2A9 | c.63C>G p.T21= | Silent (SNP) | VAF 90/341 reads (26%) | called by muse, mutect2, varscan2
- SLC43A3 | c.930G>A p.G310= | Silent (SNP) | VAF 23/233 reads (10%) | called by muse, mutect2
- SLC5A2 | c.1044T>G p.P348= | Silent (SNP) | VAF 72/307 reads (23%) | called by muse, mutect2, varscan2
- SNAPC4 | c.1641A>C p.P547= | Silent (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- SNX7 | c.906G>C p.L302= | Silent (SNP) | VAF 34/325 reads (10%) | called by muse, mutect2, varscan2
- SPATA31A6 | c.3675C>A p.A1225= | Silent (SNP) | VAF 166/734 reads (23%) | called by muse, varscan2
- SPATC1 | c.1555C>A p.R519= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- SPEG | c.5050C>A p.R1684= | Silent (SNP) | VAF 27/232 reads (12%) | catalogued as COSV56664199; called by muse, mutect2, varscan2
- ST8SIA6 | c.858G>A p.T286= | Silent (SNP) | VAF 42/470 reads (9%) | catalogued as rs748390143, COSV101112158, COSV66471233; called by muse, mutect2
- SUMF1 | c.471C>G p.V157= | Silent (SNP) | VAF 56/574 reads (10%) | catalogued as COSV55996054; called by muse, mutect2
- TLR4 | c.1371T>A p.T457= (on ENST00000355622 / NM_138554.5; = p.T417= on NM_003266.4) | Silent (SNP) | VAF 27/162 reads (17%) | called by muse, mutect2, varscan2
- TMEM63A | c.2127G>T p.L709= | Silent (SNP) | VAF 14/296 reads (5%) | called by muse, mutect2
- TNKS2 | c.927C>T p.H309= | Silent (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2
- TRPM6 | c.4482C>A p.A1494= | Silent (SNP) | VAF 66/460 reads (14%) | catalogued as COSV62521206; called by muse, mutect2, varscan2
- TUT7 | c.1216C>T p.L406= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- UBE2I | c.285C>T p.S95= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as rs755817916; called by muse, mutect2, varscan2
- UGT2B28 | c.1569G>A p.G523= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as COSV59431277; called by muse, mutect2, varscan2
- UMOD | c.810C>T p.G270= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- UNC13C | c.6036T>C p.Y2012= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- UTP25 | c.1842G>T p.T614= | Silent (SNP) | VAF 68/358 reads (19%) | called by muse, mutect2, varscan2
- UTRN | c.8619A>G p.Q2873= | Silent (SNP) | VAF 25/128 reads (20%) | called by muse, mutect2, varscan2
- VWDE | c.585A>G p.P195= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- WFIKKN2 | c.558C>T p.P186= | Silent (SNP) | VAF 104/187 reads (56%) | catalogued as COSV60959375; called by muse, mutect2, varscan2
- ZNF438 | c.486C>T p.S162= | Silent (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- AC136604.1 | n.637G>T | RNA (SNP) | VAF 33/212 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.*845G>C | 3'UTR (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- ADH1A | c.*3C>G | 3'UTR (SNP) | VAF 29/330 reads (9%) | catalogued as COSV99265995; called by muse, mutect2
- ALMS1P1 | chr2:73701034 C>A | 3'Flank (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- ANKRD18A | c.2965-1050A>C | Intron (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- ANKRD19P | chr9:92809838 C>G | 5'Flank (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501990 ins A | 5'Flank (INS) | VAF 16/154 reads (10%) | called by mutect2, pindel, varscan2
- AP000769.3 | chr11:65503649 T>C | 5'Flank (SNP) | VAF 18/126 reads (14%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500286 C>A | 5'Flank (SNP) | VAF 35/574 reads (6%) | called by muse, mutect2
- BABAM2 | c.681-4019C>G | Intron (SNP) | VAF 15/144 reads (10%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.2764-18T>A | Intron (SNP) | VAF 30/300 reads (10%) | called by muse, mutect2, varscan2
- CCDC115 | c.431-439G>T | Intron (SNP) | VAF 25/167 reads (15%) | called by muse, mutect2, varscan2
- CDC14B | c.1344-5933C>G | Intron (SNP) | VAF 8/222 reads (4%) | catalogued as COSV99685198; called by muse, mutect2
- CDK9 | c.-89G>A | 5'UTR (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- CHD5 | c.*3473G>A | 3'UTR (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812217 C>T | 3'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
- COILP1 | n.163C>T | RNA (SNP) | VAF 23/68 reads (34%) | catalogued as rs989745002; called by muse, mutect2, varscan2
- CSN1S2AP | n.179A>T | RNA (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- DCTN1 | c.3030-50G>T | Intron (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- DZANK1 | chr20:18381234 G>A | 3'Flank (SNP) | VAF 30/218 reads (14%) | catalogued as rs1009579774; called by muse, varscan2
- EDA | c.397-96110G>A | Intron (SNP) | VAF 24/134 reads (18%) | catalogued as rs1406826089; called by muse, mutect2, varscan2
- ELN | c.133+77C>A | Intron (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- EYS | c.1767-6733C>A | Intron (SNP) | VAF 50/427 reads (12%) | called by mutect2, varscan2
- FAM161A | c.*731C>T | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- FAM27E5 | n.385G>A | RNA (SNP) | VAF 26/401 reads (6%) | catalogued as rs369352933; called by muse, mutect2
- GALNT14 | n.378C>A | RNA (SNP) | VAF 87/303 reads (29%) | called by muse, mutect2, varscan2
- GARS1 | c.569+17G>T | Intron (SNP) | VAF 75/365 reads (21%) | catalogued as rs879200062; called by muse, mutect2, varscan2
- GPR89B | chr1:147995861 A>C | 3'Flank (SNP) | VAF 25/363 reads (7%) | catalogued as rs1158761051; called by muse, mutect2, varscan2
- GUCY1B1 | c.78-2224T>C | Intron (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- HAND1 | c.*40C>A | 3'UTR (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2
- HMCES | c.-14G>A | 5'UTR (SNP) | VAF 24/329 reads (7%) | called by muse, mutect2
- HOXA7 | chr7:27152830 G>T | 3'Flank (SNP) | VAF 85/288 reads (30%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-421175T>G | Intron (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- KIR3DX1 | n.737T>A | RNA (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- KLF6 | c.*2297G>A | 3'UTR (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- LINC00452 | n.736C>A | RNA (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- LINC02272 | n.336C>G | RNA (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- LRATD1 | c.*712T>A | 3'UTR (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- LRRC69 | c.933+6014C>T | Intron (SNP) | VAF 24/146 reads (16%) | called by muse, mutect2, varscan2
- MAEA | c.579+1037G>A | Intron (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- MAGI2 | c.3706+13349C>A | Intron (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.328-331G>T | Intron (SNP) | VAF 54/317 reads (17%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85464G>T | Intron (SNP) | VAF 77/432 reads (18%) | catalogued as COSV72279488; called by muse, varscan2
- MIR124-2 | n.31C>T | RNA (SNP) | VAF 16/180 reads (9%) | called by muse, mutect2
- MUC12 | c.*20C>A | 3'UTR (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- MYH7B | chr20:34975462 G>T | 5'Flank (SNP) | VAF 17/96 reads (18%) | catalogued as rs1257613766; called by muse, mutect2, varscan2
- MZT2A | c.*20G>C | 3'UTR (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- NPSR1 | c.280+1084C>A | Intron (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- OR2W5 | n.555G>A | RNA (SNP) | VAF 26/269 reads (10%) | catalogued as rs777984517; called by muse, mutect2
- OR2W5 | n.556T>G | RNA (SNP) | VAF 26/266 reads (10%) | called by muse, mutect2
- PMPCA | c.1408+155A>G | Intron (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- POTEC | c.1126+1448A>G | Intron (SNP) | VAF 24/156 reads (15%) | catalogued as rs1174388967; called by muse, mutect2, varscan2
- PPFIBP1 | c.1633+446G>C | Intron (SNP) | VAF 26/457 reads (6%) | called by muse, mutect2
- RAB4B | c.17-77T>C | Intron (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- RBBP4 | c.1212+601A>C | Intron (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- RGS4 | chr1:163069274 C>A | 5'Flank (SNP) | VAF 132/243 reads (54%) | called by muse, mutect2, varscan2
- RPL23A | c.456+64G>A | Intron (SNP) | VAF 29/377 reads (8%) | called by muse, mutect2
- SEMA4C | c.-15G>T | 5'UTR (SNP) | VAF 85/389 reads (22%) | called by muse, mutect2, varscan2
- SLC45A2 | c.-31G>T | 5'UTR (SNP) | VAF 113/325 reads (35%) | called by muse, mutect2, varscan2
- SPAG11A | chr8:7863523 A>T | 3'Flank (SNP) | VAF 29/209 reads (14%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.3789G>A | RNA (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- SSPOP | n.6879G>A | RNA (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- TRAV13-2 | c.-2T>C | 5'UTR (SNP) | VAF 44/272 reads (16%) | called by muse, mutect2, varscan2
